Surgical pathology report (de-identified scan), TCGA case TCGA-97-A4M5, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-A4M5-01A (Primary Tumor).

[page 1 of 9]
1CD-0-3

adenocarcinoma, w/ mixed subtypes
Site: lung, upper lobe c34.1 8255/3
pw 10/4/12

SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. F/S LUNG, RIGHT UPPER LOBE WEDGE
2. LEVEL 7 LYMPH NODE, RIGHT
3. LEVEL 10 LYMPH NODE, RIGHT
4. COMPLETION RIGHT UPPER LOBECTOMY
5. LEVEL 4 LYMPH NODE, RIGHT
- SEE ADDENDUM

Reason For Addendum #1: Immunohistochemistry Analysis

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

Reason For Addendum #4: Molecular Studies

DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE: WEDGE RESECTION
- INVASIVE MUCINOUS ADENOCARCINOMA (2.5 CM), SEE NOTE.
- THE STAPLE LINE MARGIN IS FREE OF TUMOR.

Note: The tumor consists of acinar (40%), micropapillary (30%) and papillary (30%) components. Results of immunohistochemical and molecular studies will be reported in addenda.

2. LYMPH NODE, RIGHT LEVEL 7: BIOPSY
- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

3. LYMPH NODE, RIGHT LEVEL 10: BIOPSY
- FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

4. LUNG, RIGHT UPPER LOBE: COMPLETION LOBECTOMY
- NO RESIDUAL TUMOR IS SEEN.

[page 2 of 9]
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

5. LYMPH NODE, RIGHT LEVEL 4: BIOPSY

- TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

Specimens: 1: F/S LUNG, RIGHT UPPER LOBE WEDGE
2: LEVEL 7 LYMPH NODE, RIGHT
3: LEVEL 10 LYMPH NODE, RIGHT
4: COMPLETION RIGHT UPPER LOBECTOMY
5: LEVEL 4 LYMPH NODE, RIGHT

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

Right Upper

Procedure: Lobectomy

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

2.5cm

MARGINS

Bronchial Margin

**Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma**

Vascular Margin: Uninvolved by invasive carcinoma

Parenchymal Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

**pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest
dimension, surrounded by lung or visceral pleura, without
bronchoscopic evidence of invasion more proximal than the lobar
bronchus (i.e., not in the main bronchus)**

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastases (pM): Not applicable

ADDITIONAL NON-TUMOR

Tumor Associated Atelectasis or Obstructive Pneumonitis:

[page 3 of 9]
Extends to the hilar region but does not involve entire lung

Additional Pathologic Finding(s): Metaplasia (specify type)
squamous

Inflammation (specify type)

organizing pneumonia

Emphysema

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

M with a 2.3 cm RUL nodule.

MACROSCOPIC DESCRIPTION:

The specimen is received in saline, in five parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'lung, right upper lobe wedge'. It consists of one lung wedge resection specimen measuring 10 x 5.5 x 2.3 cm. There is a focal area of indurated pleura overlying a mass. The pleural surface is inked black. The stapled line is removed and the underlying pleura and parenchyma is inked green. The specimen is serially sectioned to reveal a poorly circumscribed heterogeneous tan mass measuring 2.5 x 2.3 x 1.7 cm at a distance of 0.5 cm from the surgical margin and abutting the pleura. A representative section is frozen for intraoperative evaluation. Representative sections submitted, 1A-1J.

2. Part two is received in saline, labeled 'level 7 lymph node right'. It consists of one piece of anthracotic soft tissue measuring 1.5 x 1.2 x 0.5 cm. Entirely submitted, 2A.

3. Part three is received in saline, labeled 'level 10 lymph node, right'. It consists of multiple pieces of anthracotic soft tissue measuring 1.5 x 1 x 0.7 cm in aggregate, ranging in size from 0.4 cm to 1 cm in greatest dimension. The largest lymph node is bisected. Entirely submitted, 3A-3B.

4. Part four is received in saline, labeled 'completion right upper lobectomy'. It consists of one lobectomy specimen measuring 13.5 x 8 x 3.5 cm. The pleura is soft with a bluish-purple color and focal areas of hemorrhage. There is a stapled line running along the hilar aspect longitudinally measuring 12 cm in length. This line is inked green. On the opposite aspect of the specimen there is another staple line measuring 11 cm in length that is inked black. The bronchial and vascular stapled margins are removed and shaved

[page 4 of 9]
sections are submitted. Multiple lymph nodes are dissected from the hilar region, the largest measuring 0.7 cm in greatest dimension. The specimen is serially sectioned and no abnormalities are found. Representative sections submitted 4A-4F.

5. Part five is received in saline, labeled 'level 4 lymph node right '. It consists of two pieces of yellow fatty tissue measuring 0.8 x 0.6 x 0.2 cm and 0.9 x 0.3 x 0.2 cm. Each piece contains one black nodule measuring 0.2 cm. Entirely submitted, 5A.

SUMMARY OF SECTIONS:

- 1A frozen section control
- 1B-1F tumor entirely
- 1G fibrotic pleura
- 1H-1I margin, representative
- 1J normal, representative
- 2A entirely submitted
- 3A three pieces
- 3B largest piece bisected
- 4A bronchial margin
- 4B vascular margin
- 4C lymph node bisected
- 4D multiple lymph nodes
- 4E-4F representative
- 5A entirely submitted

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

- 1. Lung, right upper lobe: wedge resection (FS)
- Invasive adenocarcinoma.

Intra-Operative Consultation #1 performed by

[page 5 of 9]
ADDENDUM #1:

This addendum documents the results of our immunohistochemical stains for Part 1. The tumor cells are positive for CK7, TTF-1 and Napsin-A while negative for CK20 and CDX-2, supporting the diagnosis. The original diagnosis remains otherwise unchanged.

Addendum #1 performed by

ADDENDUM #2 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent on

The test is to be performed on

The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 1C appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to

where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #2 performed by

ADDENDUM 3:

Integrated Oncology

**MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS**

RESULTS: Positive for a p.G12C (c.34G>T) mutation in codon 12 of

[page 6 of 9]
the KRAS gene.

INTERPRETATION: Mutations in the KRAS gene are reported to correlate with poor prognosis and resistance to tyrosine kinase inhibitor therapies in patients with non-small lung cancer.

COMMENT:

KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC) patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer, 2005; 92:11-139

Pao W, Wang TY, et al. PLoS Medicine, 2005; 2(1):57-61

Eberhard DA, Johnson BE, et al. J Clin Oncol, 2005; 23:5900-5909

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8):2538-2544
CRC

DiFiore C, Blanchard F, et al. Br J Cancer, 2007; 96:1166-1169

[page 7 of 9]
Lievre A, Bachet J-B, et al. Cancer Res, 2006; 66:3992-3995,

This test was developed and its performance characteristics determined by . The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #3 performed by

ADDENDUM # 4:

EGFR Mutation Analysis

Referring Physician:

Body Site: Right upper lobe of lung

Clinical Data: Adenocarcinoma, mucinous type

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 80% tumor

[page 8 of 9]
cellularity upon pathologist review.

A frequently occurring sequence change 2361>GA (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

1. Azzoli CG, et al. J Clin Oncol. 2009; 27:6251-6266.
2. Jackman DM et al. Clin Carcinoma Res. 2009; 15:5267-5273
3. Mok TS, et al. N Engl J Med. 2009; 361:947-957
4. Sharma SV, et al. Nat Rev Carcinoma, 2007; 7:169-181.

DISCLAIMER:

This test was developed and its performance characteristics determined by . The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical

[page 9 of 9]
testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #4 performed by

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined b.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 1e632c57-c17c-4e50-bc7c-f2b6771107eb (TCGA-97-A4M5.BD386F47-1CDC-46D5-A14D-F7D27F70982F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).